Somatic mutation profile of tumor specimen TCGA-CV-5441-01A (aliquot TCGA-CV-5441-01A-01D-1512-08) from TCGA case TCGA-CV-5441, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 58.3 years (21,305 days).
Specimen TCGA-CV-5441-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55c58718-04a6-411b-830d-599cdcd83b8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5441-11A (Solid Tissue Normal), aliquot TCGA-CV-5441-11A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9db64b40-4488-4ef3-b1c5-c338b8ec8d90

The open-access MAF lists 414 somatic variants for this specimen: 306 protein-altering or splice-affecting, 100 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 256, Silent 100, Nonsense Mutation 19, Splice Site 12, Frame Shift Del 9, Frame Shift Ins 8, Intron 5, Splice Region 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4951G>A p.G1651S (on ENST00000272895 / NM_173076.3; = p.G1333S on NM_015657.3) | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs28940568, CM032169, COSV99791219; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PHIP | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768324201, COSV51504515, COSV99244662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4808A>G p.H1603R | Missense Mutation (SNP) | VAF 44/194 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57434464; called by muse, mutect2, varscan2
- SPRED1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 31/97 reads (32%) | catalogued as rs1057517941, CM093927, COSV100136330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.1459A>G p.K487E | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100383350; called by muse, mutect2, varscan2
- ABCC9 | c.3880G>T p.E1294* | Nonsense Mutation (SNP) | VAF 84/308 reads (27%) | catalogued as COSV99686527; called by muse, mutect2, varscan2
- ACACA | c.4214G>A p.R1405H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs779594669; called by muse, mutect2, varscan2
- ACSM2A | c.1098+1G>T p.X366_splice (on ENST00000219054; = p.X287_splice on NM_001308169.2) | Splice Site (SNP) | VAF 104/358 reads (29%) | catalogued as COSV99525514; called by muse, mutect2, varscan2
- ADAMTS5 | c.1581G>T p.M527I | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV99538095; called by muse, mutect2, varscan2
- ADAT1 | c.495G>T p.W165C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.806); catalogued as COSV100329269; called by muse, mutect2, varscan2
- ADCY2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100603535; called by muse, mutect2, varscan2
- ADCY2 | c.1981C>G p.L661V | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99075366; called by muse, mutect2, varscan2
- ADGRL3 | c.2657G>A p.C886Y (on ENST00000506720 / NM_001322402.2; = p.C818Y on NM_015236.6) | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101547316; called by muse, mutect2, varscan2
- ADGRL3 | c.2808C>A p.H936Q (on ENST00000506720 / NM_001322402.2; = p.H868Q on NM_015236.6) | Missense Mutation (SNP) | VAF 157/247 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.09); catalogued as COSV101547317; called by muse, mutect2, varscan2
- AFF2 | c.1993G>C p.D665H | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99662171, COSV99664436, COSV99665501; called by muse, mutect2, varscan2
- AGO1 | c.1687C>T p.L563F | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100940892; called by muse, mutect2, varscan2
- AHNAK2 | c.9790G>T p.A3264S | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV100318452, COSV60932056; called by muse, mutect2, varscan2
- AHNAK2 | c.8965G>C p.G2989R | Missense Mutation (SNP) | VAF 188/578 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs372969166, COSV100318453; called by muse, mutect2, varscan2
- AKAP1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1304756036, COSV100028170; called by muse, mutect2, varscan2
- AL121899.2 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs898155078, COSV101198598; called by muse, mutect2, varscan2
- AL669918.1 | c.2183T>A p.V728E | Missense Mutation (SNP) | VAF 119/196 reads (61%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.569); catalogued as COSV101441059; called by muse, mutect2, varscan2
- ALK | c.1780C>A p.Q594K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.194); catalogued as COSV101202481; called by muse, mutect2, varscan2
- ALOX15B | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs771993874, COSV101205668; called by muse, mutect2, varscan2
- AMER2 | c.1650C>A p.Y550* | Nonsense Mutation (SNP) | VAF 40/64 reads (63%) | catalogued as COSV100766341; called by muse, mutect2, varscan2
- AMPH | c.716C>G p.A239G | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.659); catalogued as COSV100343104; called by muse, mutect2, varscan2
- ANLN | c.2955A>T p.E985D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99732647; called by muse, mutect2, varscan2
- ANO4 | c.537G>A p.M179I (on ENST00000392977 / NM_001286615.2; = p.M144I on NM_178826.4) | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV100153463; called by muse, mutect2, varscan2
- APOB | c.8863A>G p.T2955A | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99266985; called by muse, mutect2, varscan2
- ARHGAP22 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV99985744; called by muse, mutect2, varscan2
- ARID1B | c.2517C>G p.N839K | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.255); catalogued as COSV99270938; called by muse, mutect2, varscan2
- ARRDC5 | c.868C>G p.H290D (on ENST00000381781; = p.H276D on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV101108228; called by muse, mutect2, varscan2
- ASH1L | c.6622G>T p.V2208L (on ENST00000368346 / NM_001366177.2; = p.V2203L on NM_018489.3) | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100853545; called by muse, mutect2, varscan2
- ASTN1 | c.3226G>T p.E1076* | Nonsense Mutation (SNP) | VAF 47/150 reads (31%) | catalogued as COSV100707515, COSV62506688; called by muse, varscan2
- ASTN1 | c.3112C>G p.L1038V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.979); catalogued as COSV100707516; called by muse, varscan2
- ATP8A2 | c.3310G>C p.V1104L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99683394; called by muse, mutect2, varscan2
- BACH1 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99728531; called by muse, mutect2, varscan2
- BRINP2 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs745487215, COSV100837859; called by muse, mutect2, varscan2
- C1orf116 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs370261907; called by muse, mutect2, varscan2
- C1orf159 | c.528del p.R177Gfs*20 (on ENST00000379339 / NM_001330306.2; = p.R141Gfs*20 on NM_017891.5) | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs868250296; called by mutect2, pindel, varscan2
- C3orf38 | c.375G>T p.Q125H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs779942119, COSV100007470; called by muse, mutect2, varscan2
- C8orf34 | c.1371C>A p.D457E | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100298885; called by muse, mutect2, varscan2
- CACNA2D1 | c.729-1G>C p.X243_splice | Splice Site (SNP) | VAF 27/97 reads (28%) | catalogued as COSV100667022; called by muse, mutect2, varscan2
- CACNG6 | c.704C>A p.A235D (on ENST00000252729 / NM_145814.1; = p.A164D on NM_031897.2) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV53167350, COSV99403560; called by muse, mutect2, varscan2
- CAPS2 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100158067; called by muse, mutect2, varscan2
- CAPZB | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99940151; called by muse, mutect2, varscan2
- CARD6 | c.1899G>A p.M633I | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs1311426150, COSV99621081; called by muse, mutect2
- CCER1 | c.1206G>C p.Q402H | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV100727114; called by muse, mutect2
- CDHR3 | c.40A>G p.M14V | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100488699; called by muse, mutect2, varscan2
- CDS2 | c.828+1G>A p.X276_splice | Splice Site (SNP) | VAF 46/146 reads (32%) | catalogued as COSV100986160; called by muse, mutect2, varscan2
- CELSR1 | c.2970G>T p.L990F | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99419309; called by muse, mutect2, varscan2
- CEP112 | c.993G>T p.E331D | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV101211014, COSV67140334; called by muse, mutect2, varscan2
- CHD2 | c.3341C>T p.P1114L | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101245741; called by muse, mutect2, varscan2
- CHD5 | c.3655A>T p.I1219F | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99314467; called by muse, mutect2, varscan2
- CHRNA10 | c.452G>C p.R151P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV51706338, COSV99167220; called by muse, mutect2, varscan2
- CLCN2 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99658840; called by muse, mutect2, varscan2
- CLPB | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); catalogued as COSV99578474; called by muse, varscan2
- CNTNAP5 | c.1609A>G p.S537G | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV101443879; called by muse, mutect2, varscan2
- COG4 | c.1590A>T p.Q530H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV100092090; called by muse, mutect2, varscan2
- COL11A1 | c.5290G>T p.E1764* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV62202068; called by mutect2, varscan2
- COL22A1 | c.3979-2A>C p.X1327_splice | Splice Site (SNP) | VAF 21/142 reads (15%) | catalogued as COSV100279807; called by muse, mutect2, varscan2
- COL24A1 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.217); catalogued as COSV100993779; called by muse, mutect2, varscan2
- COL3A1 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276176086, COSV100483513; called by muse, mutect2, varscan2
- COLEC12 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 215/301 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs140549407, COSV68370168; called by muse, mutect2, varscan2
- CSMD3 | c.7394C>T p.S2465F (on ENST00000297405 / NM_001363185.1; = p.S2361F on NM_052900.3) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99842529; called by muse, mutect2, varscan2
- CSMD3 | c.5245C>A p.P1749T (on ENST00000297405 / NM_001363185.1; = p.P1645T on NM_052900.3) | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99842533; called by muse, mutect2, varscan2
- CTNNA2 | c.2067A>G p.I689M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.485); catalogued as COSV100561616; called by muse, mutect2, varscan2
- CTSO | c.407G>C p.S136T | Missense Mutation (SNP) | VAF 96/169 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV101467870; called by muse, mutect2, varscan2
- DAB2 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100298204; called by muse, mutect2, varscan2
- DCDC1 | c.3628C>T p.R1210C (on ENST00000597505 / NM_001367979.1; = p.R317C on NM_020869.3) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs377384416; called by muse, mutect2, varscan2
- DLX5 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99756584; called by muse, mutect2, varscan2
- DNAH5 | c.11687C>T p.T3896I | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs367792636; called by muse, mutect2, varscan2
- DNAH5 | c.4218G>T p.K1406N | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV54213451, COSV54225200; called by muse, mutect2, varscan2
- DNAH6 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV99407994; called by muse, mutect2, varscan2
- DNAH8 | c.8948G>T p.R2983M | Missense Mutation (SNP) | VAF 87/147 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100546616, COSV59447758; called by muse, mutect2, varscan2
- DOCK10 | c.930G>T p.L310= | Splice Region (SNP) | VAF 21/117 reads (18%) | catalogued as COSV99290855; called by muse, mutect2, varscan2
- DOCK7 | c.5380G>T p.V1794F (on ENST00000635253 / NM_001367561.1; = p.V1763F on NM_033407.3) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV99225434; called by muse, mutect2, varscan2
- DOCK8 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs373168547; called by muse, mutect2, varscan2
- DPP10 | c.2385T>A p.D795E | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV100069976; called by muse, mutect2, varscan2
- DPPA4 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs752019060, COSV100169589; called by muse, mutect2, varscan2
- DTX3 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.4); catalogued as rs536336747, COSV99678182; called by muse, mutect2, varscan2
- EFCAB5 | c.1846C>A p.Q616K | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100300564; called by muse, mutect2, varscan2
- EFEMP2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1008465800, COSV57260378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFNA5 | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100321840, COSV60950236; called by muse, mutect2, varscan2
- EFNA5 | c.299G>T p.W100L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100321842; called by muse, mutect2, varscan2
- ELK4 | c.1213A>G p.N405D | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99222469; called by muse, mutect2, varscan2
- EPB41L1 | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99151314; called by muse, mutect2, varscan2
- EPB41L3 | c.2805C>A p.H935Q | Missense Mutation (SNP) | VAF 227/340 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100549880; called by muse, mutect2, varscan2
- EPHB3 | c.1087del p.R363Gfs*43 | Frame Shift Del (DEL) | VAF 48/216 reads (22%) | catalogued as COSV57809107; called by mutect2, pindel, varscan2
- ERC2 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs1205906832, COSV55649046, COSV99887690; called by muse, mutect2, varscan2
- ERCC2 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV55538474, COSV55543462, COSV99676436; called by muse, mutect2, varscan2
- FAM135B | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99357800; called by muse, mutect2, varscan2
- FAT2 | c.9026C>G p.P3009R | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99943758; called by muse, mutect2
- FILIP1 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99385683; called by muse, mutect2, varscan2
- FOXA3 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV100141473; called by muse, mutect2, varscan2
- FOXD4L5 | c.845C>A p.P282Q | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1258307892, COSV101073226; called by muse, mutect2, varscan2
- FOXN4 | c.814C>A p.L272M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV100142245, COSV100142435; called by muse, mutect2, varscan2
- FSHR | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.518); catalogued as COSV100437713; called by muse, mutect2, varscan2
- FUBP1 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 75/248 reads (30%) | catalogued as COSV53941464, COSV99628495; called by muse, mutect2, varscan2
- FYB2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100599695, COSV58590304; called by muse, mutect2, varscan2
- GABRA2 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62915135; called by muse, mutect2
- GALNT15 | c.1874G>T p.R625L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs373039243, COSV60219689; called by muse, mutect2, varscan2
- GALNT3 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV101204990, COSV67062453; called by muse, mutect2, varscan2
- GBP5 | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs1223761206, COSV100600142, COSV58592434; called by muse, mutect2, varscan2
- GPATCH8 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100132718; called by muse, mutect2, varscan2
- GPR155 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790116; called by muse, mutect2, varscan2
- GPR37 | c.1210A>T p.S404C | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100391075; called by muse, mutect2, varscan2
- GRIA4 | c.461T>C p.F154S | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1293059757, COSV99233508; called by muse, mutect2, varscan2
- GRXCR1 | c.628-2A>T p.X210_splice | Splice Site (SNP) | VAF 39/66 reads (59%) | catalogued as COSV101295730; called by muse, mutect2, varscan2
- HAO1 | c.911T>G p.L304R | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101113274; called by muse, mutect2, varscan2
- HECW2 | c.1349G>T p.S450I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99648264; called by muse, mutect2, varscan2
- HLA-F | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV52574646; called by muse, varscan2
- HMCN1 | c.466G>C p.V156L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV99633293; called by muse, mutect2, varscan2
- HSPG2 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101020965; called by muse, mutect2, varscan2
- IGKV3-15 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs1419331976; called by muse, varscan2
- INHBB | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99736080; called by muse, mutect2, varscan2
- IQGAP2 | c.2018G>T p.G673V | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99167786; called by muse, mutect2, varscan2
- ITGB8 | c.2117A>T p.Q706L | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.747); catalogued as COSV99752001; called by muse, mutect2, varscan2
- KANK1 | c.2597T>C p.L866P | Missense Mutation (SNP) | VAF 97/195 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100620011; called by muse, mutect2, varscan2
- KBTBD6 | c.433T>A p.Y145N | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101068834; called by muse, mutect2, varscan2
- KCNK9 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 98/179 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs765326608, COSV57279006; called by muse, mutect2, varscan2
- KIF4B | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1561755659, COSV101469365; called by muse, mutect2, varscan2
- KLHL7 | c.953A>G p.D318G (on ENST00000339077 / NM_001031710.3; = p.D270G on NM_018846.5) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.19); catalogued as COSV100178299; called by muse, varscan2
- KLK9 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV51591599; called by muse, mutect2
- KLRC3 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV101122924; called by muse, mutect2, varscan2
- KNDC1 | c.1907-1G>T p.X636_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100465772; called by muse, mutect2
- KNDC1 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100465776; called by muse, mutect2, varscan2
- KRTAP19-3 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.304); catalogued as COSV61854593, COSV61855062; called by muse, mutect2, varscan2
- KRTAP19-3 | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 67/219 reads (31%) | catalogued as COSV100477614; called by muse, mutect2, varscan2
- LAMA1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 192/270 reads (71%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs761620468, COSV67533271; called by muse, mutect2, varscan2
- LHX4 | c.475C>G p.R159G | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99761604, COSV99761764; called by muse, mutect2
- LILRB1 | c.1945C>A p.Q649K (on ENST00000427581; = p.Q598K on NM_006669.6) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV100207627; called by muse, mutect2, varscan2
- LRP1B | c.6962A>G p.H2321R | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101259026; called by muse, mutect2, varscan2
- LRRC4 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99975151; called by muse, mutect2, varscan2
- MACF1 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 44/139 reads (32%) | catalogued as COSV99240075; called by muse, mutect2, varscan2
- MAGEB2 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.56); PolyPhen benign (0.196); catalogued as COSV66780134; called by muse, mutect2, varscan2
- MAGEC1 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 105/185 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99596196; called by muse, mutect2, varscan2
- MAPK13 | c.639G>T p.M213I | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99275378; called by muse, mutect2, varscan2
- MAPK3 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1313150757, COSV99531863; called by muse, mutect2, varscan2
- MAPK4 | c.807G>C p.E269D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV101245790; called by muse, mutect2, varscan2
- MARCHF11 | c.935G>T p.W312L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100198144; called by muse, mutect2, varscan2
- MDGA2 | c.1205A>T p.K402I (on ENST00000399232 / NM_001113498.2; = p.K104I on NM_182830.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV100637758; called by muse, mutect2, varscan2
- MDH1B | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100982251; called by muse, mutect2, varscan2
- MDH1B | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100982253; called by muse, mutect2, varscan2
- MGAM | c.357G>A p.W119* | Nonsense Mutation (SNP) | VAF 45/177 reads (25%) | catalogued as rs1554457472, COSV101516492; called by muse, mutect2, varscan2
- MKI67 | c.5351C>T p.T1784I | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.426); catalogued as rs780760445, COSV100896858; called by muse, mutect2, varscan2
- MROH2B | c.4192G>T p.D1398Y | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432096728, COSV101270844; called by muse, mutect2, varscan2
- MSL3 | c.1057C>A p.R353S (on ENST00000312196 / NM_078629.4; = p.R187S on NM_006800.4) | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as COSV56491757, COSV56494938; called by muse, mutect2, varscan2
- MST1R | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV99619340; called by muse, mutect2, varscan2
- MYH11 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100259721; called by muse, mutect2, varscan2
- MYOZ3 | c.708A>T p.R236S | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs976454759, COSV99770823; called by muse, mutect2, varscan2
- NCAM2 | c.1985A>G p.Y662C | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99524446; called by muse, mutect2, varscan2
- NCKAP1L | c.1625G>T p.C542F | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99514735, COSV99515484; called by muse, mutect2, varscan2
- NCOA7 | c.1375G>T p.V459L | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV99997455; called by muse, mutect2, varscan2
- NDOR1 | c.401A>G p.H134R | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776861423, COSV100789072; called by muse, mutect2, varscan2
- NECAB2 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.952); catalogued as rs1173860431, COSV100534069; called by muse, mutect2, varscan2
- NES | c.4784C>T p.P1595L | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs781342603, COSV100957944; called by muse, mutect2, varscan2
- NFKBID | c.607-2A>T p.X203_splice (on ENST00000396901; = p.X355_splice on NM_032721.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 55/152 reads (36%) | catalogued as COSV100573244; called by muse, mutect2, varscan2
- NME9 | c.479G>T p.C160F (on ENST00000333911 / NM_001349024.2; = p.C99F on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV100444836; called by muse, varscan2
- NMNAT1 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.086); catalogued as COSV101020434; called by muse, mutect2, varscan2
- NMUR1 | c.963C>G p.S321R | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532065, COSV104397124, COSV59405690; called by muse, mutect2, varscan2
- NOTCH1 | c.2388del p.S797Pfs*5 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as COSV53051046; called by mutect2, pindel, varscan2
- NPAS3 | c.2003C>A p.P668Q (on ENST00000356141 / NM_001164749.2; = p.P636Q on NM_022123.3) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV100640477, COSV60856344; called by muse, mutect2, varscan2
- NR2F1 | c.1058A>T p.E353V | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100504753; called by muse, mutect2, varscan2
- OGDHL | c.2479G>T p.V827L | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100934441, COSV65101517; called by muse, mutect2, varscan2
- OR1N2 | c.269C>A p.T90N | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs1243984599, COSV101031444; called by muse, mutect2, varscan2
- OR2L13 | c.131T>C p.M44T | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100813857; called by muse, mutect2, varscan2
- OR2L2 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs891670996, COSV100824225, COSV63561835; called by muse, mutect2, varscan2
- OR2M4 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0.034); catalogued as COSV100141426; called by muse, mutect2, varscan2
- OR2T11 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100424904; called by muse, mutect2, varscan2
- OR4A16 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV100125352; called by muse, mutect2, varscan2
- OR4D6 | c.89T>A p.V30D | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs776139836, COSV100271785, COSV55659074; called by muse, mutect2, varscan2
- OR4X2 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100183307, COSV56584991; called by muse, mutect2, varscan2
- OR5D13 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100686982; called by muse, mutect2, varscan2
- OR5T2 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV100507013; called by muse, mutect2, varscan2
- OR6A2 | c.970A>G p.S324G | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100215792; called by muse, mutect2, varscan2
- P2RX3 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 95/139 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54442196, COSV99628835; called by muse, mutect2, varscan2
- P3H1 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV99355437; called by muse, mutect2, varscan2
- PAK2 | c.987del p.S330Hfs*6 | Frame Shift Del (DEL) | VAF 60/268 reads (22%) | catalogued as rs1184002054, COSV59082607; called by pindel, varscan2
- PCDHB13 | c.1575G>T p.Q525H | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99507600; called by muse, mutect2, varscan2
- PCDHB13 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV99507601; called by muse, mutect2, varscan2
- PCDHB6 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV99170615; called by muse, mutect2, varscan2
- PCDHGA11 | c.1557A>T p.Q519H | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV99543282; called by muse, mutect2, varscan2
- PCLO | c.14296C>A p.P4766T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs978828196, COSV100435528, COSV61631791; called by muse, mutect2
- PDE8B | c.1335C>A p.H445Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as COSV99367276; called by muse, mutect2, varscan2
- PDZRN3 | c.2643G>T p.Q881H | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as COSV99731175; called by muse, mutect2, varscan2
- PIK3C2A | c.1543C>G p.Q515E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99791049; called by muse, mutect2, varscan2
- PIK3CG | c.1361C>A p.S454Y | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV63249947; called by muse, mutect2, varscan2
- PKD2L1 | c.2095G>T p.G699* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV100559417; called by muse, mutect2, varscan2
- PKHD1L1 | c.4194del p.D1400Ifs*6 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as COSV65740895; called by mutect2, pindel, varscan2
- PLCXD3 | c.351C>A p.F117L | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100126066; called by muse, mutect2, varscan2
- PLXND1 | c.3506G>A p.R1169H | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200890421; called by muse, mutect2, varscan2
- POLN | c.1373G>C p.G458A | Missense Mutation (SNP) | VAF 142/259 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV101242643; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as rs751063733, COSV99461625; called by muse, mutect2, varscan2
- PPM1K | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs146041562; called by muse, mutect2, varscan2
- PRKCB | c.1928C>A p.P643H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760907855, COSV100334824; called by muse, mutect2, varscan2
- PRKD1 | c.2239C>A p.P747T | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121236; called by muse, mutect2, varscan2
- PTK2B | c.2665C>T p.R889W | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1434031157, COSV57757454; called by muse, mutect2, varscan2
- PTPN14 | c.3098C>G p.A1033G | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV100872839; called by muse, mutect2, varscan2
- PTPRT | c.1426C>A p.L476M | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV100629310; called by muse, mutect2, varscan2
- PTPRT | c.341G>T p.R114M | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100629312, COSV61960741; called by muse, mutect2, varscan2
- PYGO2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as rs1464270971, COSV100868972; called by muse, mutect2, varscan2
- RAC2 | c.372C>A p.D124E | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV99969590; called by muse, mutect2, varscan2
- RALYL | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 84/165 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV101569075; called by muse, mutect2, varscan2
- RALYL | c.773C>A p.P258H | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101569076, COSV72825778; called by muse, mutect2, varscan2
- RBM34 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs761837567, COSV100784015; called by muse, mutect2, varscan2
- RCC1L | c.1063G>T p.G355* | Nonsense Mutation (SNP) | VAF 58/173 reads (34%) | catalogued as COSV100326952; called by muse, mutect2, varscan2
- REG1A | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99286922; called by muse, mutect2, varscan2
- RELA | c.1474A>C p.M492L | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.267); catalogued as rs1283377121, COSV100425890; called by muse, mutect2, varscan2
- RELN | c.1941C>A p.N647K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.014); catalogued as COSV100634398; called by muse, mutect2, varscan2
- RFX1 | c.2608G>T p.A870S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV99586324; called by muse, mutect2, varscan2
- RIMS2 | c.3820A>T p.S1274C | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV51694080, COSV99179835; called by muse, mutect2, varscan2
- RLIM | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV100223187; called by muse, mutect2, varscan2
- RUNX2 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 120/201 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as CM095700, CM992614, COSV100767642; called by muse, mutect2, varscan2
- RYR2 | c.14227C>A p.L4743I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100772078; called by muse, mutect2, varscan2
- S1PR3 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100822589; called by muse, mutect2, varscan2
- SAMD15 | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99375139; called by muse, mutect2, varscan2
- SEL1L2 | c.1792T>C p.Y598H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.525); catalogued as rs1234378000, COSV99533653; called by muse, mutect2, varscan2
- SERTAD1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV100781698; called by muse, mutect2, varscan2
- SH2D1A | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758349, COSV63578461, COSV63579904; called by muse, mutect2, varscan2
- SH3TC2 | c.3280T>A p.F1094I | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100102170; called by muse, mutect2, varscan2
- SHANK3 | c.1993G>T p.G665W | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs763010846, COSV99437543; called by muse, mutect2, varscan2
- SIPA1L3 | c.2818G>T p.A940S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99729869; called by muse, mutect2, varscan2
- SKI | c.484A>T p.K162* | Nonsense Mutation (SNP) | VAF 17/22 reads (77%) | catalogued as COSV101049512; called by muse, mutect2, varscan2
- SLC13A1 | c.812+1G>A p.X271_splice | Splice Site (SNP) | VAF 36/77 reads (47%) | catalogued as rs150284958; called by muse, mutect2, varscan2
- SLC13A1 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs199595316; called by muse, mutect2, varscan2
- SLC25A12 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99785279; called by muse, mutect2, varscan2
- SLC25A20 | c.722C>G p.P241R | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100033841; called by muse, mutect2, varscan2
- SLC26A7 | c.380C>A p.T127N | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); catalogued as COSV99403989; called by muse, mutect2
- SLC7A14 | c.712G>T p.G238W | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.733); catalogued as rs141548910, COSV51582460; called by muse, mutect2, varscan2
- SLC8A3 | c.1549T>C p.C517R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as COSV100776307; called by muse, mutect2, varscan2
- SLIT3 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV100269043; called by muse, mutect2, varscan2
- SMARCC2 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.059); catalogued as COSV99910918; called by muse, mutect2, varscan2
- SPIN4 | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100633392; called by muse, mutect2, varscan2
- SPNS1 | c.1323C>T p.I441= | Splice Region (SNP) | VAF 63/167 reads (38%) | catalogued as rs770063032, COSV100209202; called by muse, mutect2, varscan2
- SSTR4 | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99658707; called by muse, varscan2
- STAC | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.047); catalogued as COSV99830449; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2957G>A p.S986N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as COSV100562092; called by muse, mutect2, varscan2
- SYK | c.98dup p.M34Hfs*3 | Frame Shift Ins (INS) | VAF 16/35 reads (46%) | catalogued as rs1182878074; called by mutect2, pindel, varscan2
- SYNE1 | c.24722A>T p.H8241L (on ENST00000367255 / NM_182961.4; = p.H8170L on NM_033071.3) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV99573551; called by muse, mutect2, varscan2
- SYNE1 | c.12133C>A p.L4045M (on ENST00000367255 / NM_182961.4; = p.L3974M on NM_033071.3) | Missense Mutation (SNP) | VAF 118/219 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99573565; called by muse, mutect2, varscan2
- SYNE1 | c.11410G>C p.V3804L (on ENST00000367255 / NM_182961.4; = p.V3789L on NM_033071.3) | Missense Mutation (SNP) | VAF 228/431 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs889111484, COSV99573571; called by muse, mutect2, varscan2
- SYNE1 | c.4150-1G>T p.X1384_splice (on ENST00000367255 / NM_182961.4; = p.X1391_splice on NM_033071.3) | Splice Site (SNP) | VAF 92/162 reads (57%) | catalogued as COSV99573577; called by muse, mutect2, varscan2
- TAS2R43 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101115282; called by muse, varscan2
- TBKBP1 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100659189; called by muse, mutect2, varscan2
- TDRD10 | c.797+2T>A p.X266_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99427585; called by muse, mutect2, varscan2
- TGM6 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99172110; called by muse, mutect2, varscan2
- THSD7A | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101448827; called by muse, mutect2, varscan2
- TJP2 | c.1641G>T p.E547D | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV99601612; called by muse, mutect2, varscan2
- TMC1 | c.2248G>T p.A750S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.479); catalogued as COSV52782621; called by muse, mutect2, varscan2
- TMC2 | c.1614A>G p.I538M | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.866); catalogued as COSV100727811; called by muse, mutect2, varscan2
- TNNI3K | c.2377C>A p.L793M | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.146); catalogued as COSV58553545; called by muse, mutect2, varscan2
- TRHDE | c.1703G>T p.W568L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99671854; called by muse, mutect2, varscan2
- TRIM22 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101181434; called by muse, mutect2, varscan2
- TRIM43 | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as COSV99720033; called by muse, mutect2, varscan2
- TRIM58 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825003, COSV100825218, COSV63569534; called by muse, mutect2
- TRPA1 | c.934A>G p.M312V | Missense Mutation (SNP) | VAF 97/184 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV100084830; called by muse, mutect2, varscan2
- TSNARE1 | c.1197G>T p.M399I | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56185074; called by muse, mutect2
- TTN | c.52240G>T p.E17414* (on ENST00000591111; = p.E9990* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 70/276 reads (25%) | catalogued as COSV100623138; called by muse, mutect2, varscan2
- TTN | c.25621G>A p.E8541K (on ENST00000591111; = p.E7614K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | PolyPhen benign (0.069); catalogued as COSV100623139; called by muse, mutect2, varscan2
- UBE2L3 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100641555; called by muse, mutect2, varscan2
- UNC79 | c.5786T>A p.L1929Q (on ENST00000393151 / NM_001346218.2; = p.L1752Q on NM_020818.5) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99829206; called by muse, mutect2, varscan2
- USH2A | c.5111A>C p.N1704T | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100239489; called by muse, mutect2, varscan2
- UTRN | c.2320G>T p.E774* | Nonsense Mutation (SNP) | VAF 129/246 reads (52%) | catalogued as COSV100840176; called by muse, mutect2, varscan2
- VPS13C | c.8728T>C p.W2910R (on ENST00000644861 / NM_020821.3; = p.W2867R on NM_017684.5) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99829567; called by muse, mutect2, varscan2
- VWC2L | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100436162; called by muse, mutect2, varscan2
- WDHD1 | c.1963G>T p.G655C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as COSV100777625; called by muse, mutect2, varscan2
- WDPCP | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as COSV99706274; called by muse, mutect2, varscan2
- WDR18 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.114); catalogued as COSV99243002; called by muse, mutect2, varscan2
- WDR3 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100832279; called by muse, mutect2, varscan2
- WDR46 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 135/203 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101004821; called by muse, mutect2, varscan2
- XIRP2 | c.2650T>A p.F884I (on ENST00000628543; = p.F1059I on NM_152381.6) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54737201; called by muse, mutect2, varscan2
- XIRP2 | c.7876C>A p.P2626T (on ENST00000628543; = p.P2801T on NM_152381.6) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99745801; called by muse, mutect2, varscan2
- XKR9 | c.799G>T p.V267F | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101281962; called by muse, mutect2, varscan2
- YY1AP1 | c.2176G>T p.G726W (on ENST00000295566 / NM_139118.2; = p.G669W on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as COSV99804462; called by muse, mutect2, varscan2
- ZAP70 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV53856215, COSV99385818, COSV99386116; called by muse, mutect2, varscan2
- ZBED4 | c.1765G>T p.G589W | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99351485; called by muse, mutect2, varscan2
- ZEB1 | c.3304G>T p.A1102S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV100314773, COSV58041493; called by muse, mutect2, varscan2
- ZIC1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51550649; called by muse, varscan2
- ZMYM3 | c.2051A>C p.Q684P | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100078197; called by muse, mutect2, varscan2
- ZNF257 | c.1115A>T p.Y372F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV101448143; called by muse, mutect2, varscan2
- ZNF280A | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 58/176 reads (33%) | catalogued as rs778330477, COSV57480885, COSV57481443; called by muse, mutect2
- ZNF280A | c.587T>G p.V196G | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.17); catalogued as COSV100131169; called by muse, mutect2
- ZNF30 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs369087430; called by muse, mutect2, varscan2
- ZNF597 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100072089; called by muse, mutect2
- ZNF616 | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100348514; called by muse, mutect2, varscan2
- ZNF835 | c.7G>T p.G3* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV101606389; called by muse, mutect2, varscan2
- ZNF98 | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as rs867646673, COSV100757562; called by muse, mutect2, varscan2
- ACTN2 | c.244del p.X82_splice | Splice Site (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- ARID1B | c.2774_2775del p.V925Efs*3 | Frame Shift Del (DEL) | VAF 32/67 reads (48%) | called by pindel, varscan2
- CDC5L | c.1524T>A p.D508E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2
- CHRNA5 | c.269dup p.N90Kfs*24 | Frame Shift Ins (INS) | VAF 82/219 reads (37%) | called by mutect2, pindel, varscan2
- CLSTN2 | c.389del p.G130Vfs*21 | Frame Shift Del (DEL) | VAF 44/154 reads (29%) | called by mutect2, pindel, varscan2
- FBXO11 | c.1167dup p.C390Mfs*3 (on ENST00000403359 / NM_001190274.2; = p.C306Mfs*3 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 32/114 reads (28%) | called by mutect2, pindel, varscan2
- HMCN1 | c.727dup p.S243Kfs*17 | Frame Shift Ins (INS) | VAF 18/94 reads (19%) | called by mutect2, pindel, varscan2
- IGHV3-73 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IGHV4-28 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.709); called by muse, varscan2
- IGKV4-1 | c.57C>A p.Y19* | Nonsense Mutation (SNP) | VAF 28/105 reads (27%) | called by muse, mutect2, varscan2
- KCNJ3 | c.1115T>A p.I372K | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KDM6A | c.164dup p.L56Pfs*9 | Frame Shift Ins (INS) | VAF 16/31 reads (52%) | called by mutect2, pindel, varscan2
- OR8D4 | c.583del p.D195Mfs*4 | Frame Shift Del (DEL) | VAF 77/210 reads (37%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.307dup p.R103Kfs*4 | Frame Shift Ins (INS) | VAF 65/160 reads (41%) | called by mutect2, pindel, varscan2
- SAMD3 | c.754del p.R252Efs*12 | Frame Shift Del (DEL) | VAF 47/294 reads (16%) | called by mutect2, pindel, varscan2
- SBF1 | c.2966_2967+16del p.X989_splice | Splice Site (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- SLC25A21 | c.259dup p.R87Kfs*9 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- SPATA16 | c.193dup p.M65Nfs*12 | Frame Shift Ins (INS) | VAF 79/384 reads (21%) | called by mutect2, pindel, varscan2
- ZNF84 | c.2190G>T p.Q730H | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS18 | c.1677C>G p.P559= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99273681; called by muse, mutect2, varscan2
- AMIGO3 | c.1365C>T p.V455= | Silent (SNP) | VAF 54/154 reads (35%) | catalogued as rs758864363, COSV57537775; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5737C>T p.L1913= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV99783987; called by muse, mutect2, varscan2
- AREL1 | c.462C>T p.Y154= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs778655379, COSV100707634, COSV62665820; called by muse, mutect2, varscan2
- BCOR | c.642A>T p.S214= | Silent (SNP) | VAF 58/80 reads (73%) | catalogued as COSV100653702; called by muse, mutect2, varscan2
- BPIFB4 | c.1524C>A p.V508= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs767062633, COSV100971488; called by muse, mutect2, varscan2
- CBX8 | c.936C>A p.G312= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV53936309, COSV99485946; called by muse, mutect2, varscan2
- CCSER1 | c.1809G>T p.A603= | Silent (SNP) | VAF 63/105 reads (60%) | catalogued as rs369689377, COSV100394742; called by muse, mutect2, varscan2
- CEP192 | c.3123G>T p.T1041= | Silent (SNP) | VAF 89/592 reads (15%) | catalogued as rs940502075, COSV100381777; called by muse, mutect2, varscan2
- CHD3 | c.3333G>A p.T1111= | Silent (SNP) | VAF 102/154 reads (66%) | catalogued as rs748618377, COSV100391479; called by muse, mutect2, varscan2
- CLCN1 | c.1134G>A p.K378= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as rs981464352, COSV100578332; called by muse, mutect2, varscan2
- CNR1 | c.987G>A p.V329= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as COSV100759282; called by muse, mutect2, varscan2
- COL6A2 | c.1035G>A p.K345= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100154016; called by muse, mutect2, varscan2
- CTNNA3 | c.1422G>T p.A474= | Silent (SNP) | VAF 48/153 reads (31%) | catalogued as rs372258059, COSV101050973; called by muse, mutect2, varscan2
- CX3CR1 | c.69T>A p.I23= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100843255; called by muse, mutect2, varscan2
- CXCR3 | c.597C>T p.N199= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV101031698, COSV101031751; called by muse, mutect2, varscan2
- DAB2 | c.1491C>A p.P497= | Silent (SNP) | VAF 63/257 reads (25%) | catalogued as COSV100297985, COSV100298207; called by muse, mutect2, varscan2
- DCBLD1 | c.207A>G p.E69= | Silent (SNP) | VAF 43/292 reads (15%) | catalogued as COSV99757913; called by muse, mutect2, varscan2
- EDAR | c.24G>T p.T8= | Silent (SNP) | VAF 59/187 reads (32%) | catalogued as rs771046519, COSV51500015, COSV51500127, COSV99304016; called by muse, mutect2, varscan2
- EHD3 | c.1431C>T p.P477= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV100434828; called by muse, mutect2, varscan2
- ELFN2 | c.2139C>T p.P713= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs764038571, COSV101297518; called by muse, mutect2
- EZHIP | c.1446T>A p.P482= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as COSV100539815; called by muse, mutect2, varscan2
- FAM83B | c.2286G>A p.K762= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as COSV100174800; called by muse, mutect2, varscan2
- GHITM | c.112C>T p.L38= | Silent (SNP) | VAF 63/207 reads (30%) | catalogued as COSV100930116; called by muse, mutect2, varscan2
- GIGYF1 | c.2250G>C p.V750= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99309767; called by muse, mutect2, varscan2
- GLT1D1 | c.192C>G p.L64= | Silent (SNP) | VAF 92/293 reads (31%) | catalogued as COSV99897167; called by muse, mutect2, varscan2
- GPX4 | c.375C>G p.V125= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100684865; called by muse, mutect2, varscan2
- HDDC2 | c.339A>T p.L113= | Silent (SNP) | VAF 192/345 reads (56%) | catalogued as COSV100600272; called by muse, mutect2, varscan2
- HECW1 | c.504G>T p.G168= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as COSV101224122; called by muse, mutect2, varscan2
- ICE2 | c.978A>T p.S326= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as COSV99831716; called by muse, mutect2, varscan2
- IFNL2 | c.304C>T p.L102= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100122113; called by muse, mutect2, varscan2
- IGHG2 | c.903C>A p.V301= | Silent (SNP) | VAF 70/232 reads (30%) | catalogued as rs1174839044; called by muse, varscan2
- IGKV1-12 | c.36C>A p.L12= | Silent (SNP) | VAF 66/558 reads (12%) | called by muse, varscan2
- IGLV3-22 | c.243T>A p.S81= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs780296210; called by muse, mutect2, varscan2
- INO80B | c.951G>C p.P317= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99270693; called by muse, mutect2, varscan2
- KCNJ3 | c.120G>A p.K40= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV54536467, COSV99716273, COSV99716479; called by muse, mutect2, varscan2
- KIDINS220 | c.4728G>C p.A1576= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as COSV99876192; called by muse, mutect2, varscan2
- KLHL1 | c.549T>C p.S183= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as COSV100917835; called by muse, mutect2, varscan2
- KRT72 | c.1509C>T p.S503= | Silent (SNP) | VAF 105/344 reads (31%) | catalogued as COSV99537412; called by muse, mutect2, varscan2
- LRP2 | c.12003C>T p.D4001= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99789670; called by muse, mutect2, varscan2
- LRRTM1 | c.696C>A p.L232= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as COSV54440438; called by muse, mutect2, varscan2
- LRRTM1 | c.495G>C p.T165= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV99702921; called by muse, mutect2, varscan2
- MAPRE1 | c.660G>A p.K220= | Silent (SNP) | VAF 72/242 reads (30%) | catalogued as COSV100980407; called by muse, mutect2, varscan2
- MED14 | c.4251C>T p.N1417= | Silent (SNP) | VAF 47/64 reads (73%) | catalogued as rs766594428, COSV100247576; called by muse, mutect2, varscan2
- MED23 | c.198T>C p.F66= | Silent (SNP) | VAF 44/262 reads (17%) | catalogued as rs1378988964, COSV100645273; called by muse, mutect2, varscan2
- MKRN3 | c.471G>A p.A157= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs762104625, COSV58810296, COSV58812359; called by muse, mutect2, varscan2
- MMP14 | c.972C>T p.D324= | Silent (SNP) | VAF 56/219 reads (26%) | catalogued as rs1424403827, COSV100314242; called by muse, mutect2, varscan2
- MTHFD1 | c.819C>T p.G273= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs769272465, COSV99387169; called by muse, mutect2, varscan2
- MYH8 | c.3435A>G p.E1145= | Silent (SNP) | VAF 116/171 reads (68%) | catalogued as rs904798595, COSV101238571; called by muse, mutect2, varscan2
- NALCN | c.1146G>A p.R382= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs773010148, COSV99216776; called by muse, mutect2, varscan2
- NLGN1 | c.1545C>A p.I515= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV100849793, COSV64325490; called by muse, mutect2, varscan2
- NWD1 | c.1551G>A p.P517= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs148902093; called by muse, mutect2, varscan2
- NYAP2 | c.669G>A p.P223= | Silent (SNP) | VAF 19/268 reads (7%) | catalogued as rs371567983; called by muse, mutect2
- NYNRIN | c.3861C>G p.P1287= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as COSV101230649, COSV66842114, COSV66843917; called by muse, mutect2, varscan2
- OR10H5 | c.852C>A p.P284= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100454774, COSV58278604; called by muse, mutect2, varscan2
- OR13J1 | c.417G>C p.R139= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV100940823; called by muse, mutect2, varscan2
- OR2B6 | c.778C>T p.L260= | Silent (SNP) | VAF 120/188 reads (64%) | catalogued as COSV99773815; called by muse, mutect2, varscan2
- OR4C46 | c.360C>T p.H120= | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as COSV100060867; called by muse, mutect2, varscan2
- OR51V1 | c.258G>A p.G86= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV100343451; called by muse, mutect2, varscan2
- OR56A1 | c.198C>T p.L66= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV100360522, COSV57362321; called by muse, mutect2, varscan2
- PBK | c.654G>A p.V218= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs751148854, COSV100107424; called by muse, mutect2, varscan2
- PCDH15 | c.855C>A p.A285= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV100225197, COSV57312987; called by muse, mutect2, varscan2
- PCDH17 | c.2307G>T p.L769= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV100931802; called by muse, mutect2, varscan2
- PCDHB9 | c.2235G>A p.L745= | Silent (SNP) | VAF 134/254 reads (53%) | catalogued as COSV53381086; called by muse, mutect2, varscan2
- PCDHGA7 | c.723C>T p.V241= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99543281; called by muse, mutect2, varscan2
- PCDHGC5 | c.138G>C p.G46= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV52763653, COSV99341484; called by muse, mutect2, varscan2
- PGLS | c.759G>A p.E253= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99395743; called by muse, mutect2, varscan2
- PIK3CG | c.1362C>A p.S454= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as COSV100783048; called by muse, mutect2, varscan2
- PIP5K1B | c.351G>A p.L117= | Silent (SNP) | VAF 61/206 reads (30%) | catalogued as COSV99599439; called by muse, mutect2, varscan2
- POLE | c.5688A>G p.S1896= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs1284129543, COSV100267671; called by muse, mutect2, varscan2
- POLG | c.739C>T p.L247= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs754696832, COSV99174960; called by muse, mutect2, varscan2
- POM121L12 | c.576C>T p.F192= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs762091356, COSV68692173; called by muse, mutect2, varscan2
- PPP1R16B | c.157C>A p.R53= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1447507825, COSV100239815; called by muse, mutect2
- PROKR2 | c.738C>A p.I246= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV99450495; called by muse, mutect2, varscan2
- RASAL1 | c.1686G>T p.P562= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as COSV99921661; called by muse, mutect2, varscan2
- REG1A | c.315C>A p.P105= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs3181912, COSV99286925; called by muse, mutect2, varscan2
- REN | c.145C>A p.R49= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as CM053391, COSV99689653; called by muse, mutect2, varscan2
- SEMA6D | c.681A>T p.I227= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100317362; called by muse, mutect2, varscan2
- SIPA1L1 | c.5049A>G p.V1683= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100665841; called by muse, mutect2, varscan2
- SLC15A4 | c.879A>G p.Q293= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as COSV99903728; called by muse, mutect2, varscan2
- SLC2A3 | c.537G>T p.G179= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs753157930, COSV50000799, COSV99306838; called by muse, mutect2, varscan2
- SLC35F1 | c.1083C>A p.A361= | Silent (SNP) | VAF 55/360 reads (15%) | catalogued as COSV100837956; called by muse, mutect2, varscan2
- SLC35F3 | c.669C>T p.Y223= (on ENST00000366617 / NM_001300845.1; = p.Y292= on NM_173508.4) | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as rs764578116, COSV64019873; called by muse, mutect2, varscan2
- SLC39A10 | c.105G>A p.A35= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs747809071, COSV100660713; called by muse, mutect2, varscan2
- SLC39A4 | c.117G>T p.L39= | Silent (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1077C>G p.P359= | Silent (SNP) | VAF 78/285 reads (27%) | catalogued as COSV99579755; called by muse, mutect2, varscan2
- SMAD6 | c.1389C>T p.S463= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99994268; called by muse, mutect2, varscan2
- SSH2 | c.1527A>G p.E509= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as rs1240515329, COSV99282689; called by muse, mutect2, varscan2
- SSTR4 | c.1053C>A p.L351= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV99658704; called by muse, varscan2
- SYNE1 | c.17439C>T p.T5813= (on ENST00000367255 / NM_182961.4; = p.T5742= on NM_033071.3) | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV54897414, COSV99573556; called by muse, mutect2, varscan2
- TMEM132D | c.291C>T p.Y97= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs760324975, COSV70622058; called by muse, mutect2, varscan2
- TMPRSS6 | c.2286C>T p.L762= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs368136786; called by muse, mutect2, varscan2
- TRPM1 | c.2790C>T p.I930= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as COSV99856379; called by muse, mutect2, varscan2
- TRPM4 | c.1251C>T p.D417= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99420573; called by muse, mutect2, varscan2
- TYR | c.339A>C p.T113= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV99634931; called by muse, mutect2, varscan2
- USP24 | c.3306G>A p.R1102= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs370042721; called by muse, mutect2, varscan2
- WNK4 | c.1353G>T p.P451= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99891056; called by muse, mutect2, varscan2
- ZBTB20 | c.1198C>A p.R400= (on ENST00000474710 / NM_001164342.2; = p.R327= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as COSV100614694; called by muse, mutect2, varscan2
- ZFP90 | c.1704C>T p.L568= | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as COSV101238798; called by muse, mutect2, varscan2
- ZNF536 | c.2277T>C p.T759= | Silent (SNP) | VAF 54/170 reads (32%) | catalogued as COSV100835583; called by muse, mutect2, varscan2
- GLRXP3 | n.62C>A | RNA (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- LDB3 | c.690-4826G>T | Intron (SNP) | VAF 97/390 reads (25%) | catalogued as COSV53943727, COSV99555687, COSV99555740; called by muse, mutect2, varscan2
- MGAM | c.4618+286T>A | Intron (SNP) | VAF 26/88 reads (30%) | catalogued as COSV101527620; called by muse, mutect2, varscan2
- MOXD1 | c.264+8905G>T | Intron (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100914395; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671088 A>C | 3'Flank (SNP) | VAF 51/174 reads (29%) | called by muse, mutect2, varscan2
- NACA | c.71-4133_71-4127del | Intron (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- SGIP1 | c.99+1047C>A | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as rs1318390590, COSV99392412; called by muse, mutect2
- SNORD115-14 | n.81C>A | RNA (SNP) | VAF 74/244 reads (30%) | called by muse, mutect2, varscan2
